Surgical pathology report (de-identified scan), TCGA case TCGA-BA-4076, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site UNC, specimen TCGA-BA-4076-01A (Primary Tumor).

[page 1 of 2]
SURGICAL PATHOLOGY

Diagnosis:

A: False vocal cord, right posterior, biopsy

- At least squamous cell carcinoma in situ, focally suspicious for invasive squamous carcinoma, no definite invasive carcinoma identified (see light microscopy).

B: Arytenoid, left, biopsy

- In situ squamous cell carcinoma with severe chronic inflammation, no invasive carcinoma identified (see light microscopy)

Comment:

None.

Clinical History:

The patient is with dysphagia who undergoes triple panendoscopy.

Gross Description:

Two appropriately labeled containers are received.

Specimen: A

SITE: posterior right false vocal cord

METHOD: biopsy

MEASURE: 0.3 x 0.3 x 0.2 cm

COMMENT: pink/tan irregularly shaped soft tissue fragment

BLOCK: A1,

Specimen: B

SITE: left arytenoid

METHOD: biopsy

MEASURE: 0.6 x 0.4 x 0.3 cm

COMMENT: pink/tan irregularly shaped soft tissue fragment

BLOCK: B1,

[page 2 of 2]
Light Microscopy:

Light microscopic examination is performed [REDACTED]

Similar findings were observed in both initial and deeper recut levels.

Source: NCI Genomic Data Commons file e2f8c29e-94d5-4f6f-a526-d6f56e015f68 (TCGA-BA-4076.0360EEA9-6B01-4734-A72A-3BF3D4ED0249.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).